Gene-level copy-number profile of tumor specimen ALCH-AE94-TTP1-A from ALCHEMIST case ALCH-AE94, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 84.0 years (30,668 days).
Specimen ALCH-AE94-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 59a7a6a9-292b-48c4-ade8-7e1545dfeeaa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE94-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/3bd41ae2-57b1-47a4-8fb2-6813e69329f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 665; copy number 1: 16,059; copy number 2: 33,435; copy number 3: 7,200; copy number 4: 294; copy number 5: 458; copy number 6: 775; copy number 7: 1; copy number 10: 4; copy number 11: 1; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 134 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,491,160–131,536,988, 4 genes (within-gene range 0–1): MIR4784, SMPD4BP, CCDC74A, MED15P4.
- chr3:49,140,086–49,535,618, 20 genes: LAMB2P1, CCDC71, KLHDC8B, C3orf84, IHO1, AC121247.2, AC121247.1, C3orf62, Y_RNA, MIR4271, USP4, GPX1, RHOA, RHOA-IT1, TCTA, AC104452.1, AMT, NICN1, RNA5SP130, DAG1.
- chr3:75,415,070–75,538,029, 5 genes: ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–1): RPS3AP15.
- chr4:188,091,273–188,161,157, 6 genes: TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434.
- chr6:60,281,444–60,546,660, 1 gene: AC244258.1.
- chr6:107,065,182–107,459,564, 5 genes: BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr6:154,706,643–154,707,795, 1 gene: AL591499.1.
- chr6:154,832,697–155,257,723, 6 genes (within-gene range 0–2): TIAM2, AL121952.1, MIR1273C, U8, AL136228.1, AL596202.1.
- chr8:30,192,429–30,250,092, 4 genes: AC026979.4, AC026979.3, HSPA8P11, AC090820.1.
- chr8:30,678,066–30,767,006, 3 genes: GSR, UBXN8, HIKESHIP3.
- chr8:73,905,357–73,984,883, 5 genes: GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3.
- chr8:80,204,606–80,484,481, 6 genes (within-gene range 0–1): RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1.
- chr9:60,914,407–62,435,199, 35 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2.
- chr10:34,815,767–34,816,386, 1 gene: PARD3-AS1.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.
- chr12:121,888,732–121,921,470, 4 genes (within-gene range 0–1): PSMD9, AC069503.2, Metazoa_SRP, RNU7-170P.
- chr13:98,671,980–98,672,278, 1 gene: RN7SL60P.
- chr16:16,356,224–16,398,594, 4 genes: PKD1P2, MIR6511A3, NPIPA7, AC136619.1.
- chr16:33,802,764–33,803,217, 1 gene: IGHV3OR16-12.
- chr17:22,331,597–22,332,410, 1 gene: AC087575.1.
- chr19:29,901,696–29,917,830, 2 genes: AC008798.1, AC008507.3.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.
- chr21:36,130,489–36,419,015, 12 genes: MEMO1P1, CBR3-AS1, RPS9P1, CBR3, DOP1B, RPL3P1, SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,240 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,968,609–87,992,858, 3 genes, copy number 6: NDUFB4P7, WBP1P2, ANAPC1P5.
- chr4:38,758,791–39,032,922, 7 genes, copy number 5: RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156.
- chr4:41,220,074–49,212,624, 101 genes, copy number 5 (broad region; genes not listed).
- chr5:135,802,985–135,803,075, 1 gene, copy number 7: MIR5692C1.
- chr7:37,032–43,956,136, 740 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:44,044,640–56,687,366, 223 genes, copy number 5–6 (broad region; genes not listed).
- chr7:57,067,950–63,562,588, 90 genes, copy number 5–14 (broad region; genes not listed).
- chr11:112,967–126,123, 2 genes, copy number 10: AC069287.1, CICP23.
- chr14:94,146,128–94,279,734, 1 gene, copy number 5: PPP4R4.
- chr16:33,808,778–33,810,767, 1 gene, copy number 5: AC136428.3.
- chr22:18,361,820–19,566,839, 70 genes, copy number 5–6 (broad region; genes not listed).
- chr22:21,473,000–21,517,533, 1 gene, copy number 11: PI4KAP2.

Autosomal genes at a single copy (total copy number 1): 13,747. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
